Gene-level copy-number profile of tumor specimen TCGA-56-8625-01A from TCGA case TCGA-56-8625, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.2 years (24,188 days).
Specimen TCGA-56-8625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f03ddf31-0f53-4418-a69f-2be6b9eca664.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-8625-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/560b61a0-03bb-4844-868e-5a14181f3793

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 30; copy number 2: 74; copy number 3: 2,783; copy number 4: 14,488; copy number 5: 29,587; copy number 6: 7,431; copy number 7: 2,728; copy number 8: 1,851; copy number 9: 475; copy number 10: 244; copy number 11: 18; copy number 13: 42; copy number 14: 14; copy number 15: 13; copy number 16: 16; copy number 32: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-8625-01A-11D-2391-01): tumor purity 0.37, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 33 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,999,313–22,536,322, 18 genes, copy number 11–15 (within-gene range 5–15): AC115619.1, APOB, AC010872.1, AC010872.2, TDRD15, AC067959.1, AC018742.1, AC011752.1, NUTF2P8, AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830.
- chr8:104,590,733–106,060,524, 14 genes, copy number 14 (within-gene range 7–14): ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA.
- chr14:53,685,139–53,850,882, 1 gene, copy number 11 (within-gene range 5–11): LINC02331.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
